Gene-level copy-number profile of tumor specimen TCGA-YU-A94A-01A from TCGA case TCGA-YU-A94A, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.0 years (14,991 days).
Specimen TCGA-YU-A94A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65c1728d-bc27-4dcf-bfd4-021996954084.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A94A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,856 have no estimate.
https://portal.gdc.cancer.gov/files/816bffa2-4a87-4c1a-94ee-1971b6ec871d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 765; copy number 2: 27,984; copy number 3: 26,808; copy number 4: 2,372; copy number 5: 4; copy number 8: 16; copy number 9: 812; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:49,067,610–49,083,097, 3 genes: AC084851.3, AC084851.1, UBTFL7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 831 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 831 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
